Somatic mutation profile of tumor specimen TARGET-30-PAKXDZ-01A (aliquot TARGET-30-PAKXDZ-01A-01W) from TARGET case TARGET-30-PAKXDZ, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 2.3 years (828 days).
Specimen TARGET-30-PAKXDZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6823a262-05d1-4d07-9bbd-0fdadf740fc4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAKXDZ-10A (Blood Derived Normal), aliquot TARGET-30-PAKXDZ-10A-01W; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1e8de094-6a55-4c5c-ab81-6bcf1ba873de

The open-access MAF lists 27 somatic variants for this specimen: 16 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 10, Splice Site 2, Frame Shift Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALK | c.3512T>A p.I1171N | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1057519698, COSV66556242, COSV66564577, COSV66567934; ClinVar: pathogenic; called by muse, varscan2
- AKAP4 | c.544G>T p.A182S | Missense Mutation (SNP) | VAF 257/664 reads (39%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as COSV62075205; called by muse, mutect2, varscan2
- ARR3 | c.1076+1G>T p.X359_splice | Splice Site (SNP) | VAF 21/51 reads (41%) | catalogued as COSV52104918; called by muse, mutect2, varscan2
- CHD2 | c.1063G>A p.V355I | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.107); catalogued as COSV59121850; called by muse, mutect2, varscan2
- DPP10 | c.172C>G p.P58A | Missense Mutation (SNP) | VAF 63/171 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV59709808; called by muse, mutect2, varscan2
- FAM50B | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.028); catalogued as rs768080374, COSV66654570, COSV66655272; called by muse, mutect2, varscan2
- GJA5 | c.408G>T p.W136C | Missense Mutation (SNP) | VAF 65/122 reads (53%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.662); catalogued as COSV54785941; called by muse, mutect2, varscan2
- KAT14 | c.424C>T p.R142C | Missense Mutation (SNP) | VAF 143/361 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1383004396, COSV66607912; called by muse, mutect2, varscan2
- KCNH6 | c.1141C>A p.L381M | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59004791, COSV59006376; called by muse, mutect2, varscan2
- KRT35 | c.326C>A p.A109D | Missense Mutation (SNP) | VAF 61/183 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55844127; called by muse, mutect2, varscan2
- MUC3A | c.8330T>C p.I2777T | Missense Mutation (SNP) | VAF 40/149 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.006); catalogued as COSV100114136; called by muse, mutect2, varscan2
- PEX11B | c.774G>T p.K258N | Missense Mutation (SNP) | VAF 93/183 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV65198554; called by muse, mutect2, varscan2
- PLEKHA7 | c.2934+1G>T p.X978_splice | Splice Site (SNP) | VAF 11/29 reads (38%) | catalogued as COSV60580839; called by muse, mutect2, varscan2
- SCN4A | c.3986A>G p.K1329R | Missense Mutation (SNP) | VAF 33/40 reads (83%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as rs754942929, COSV71126819, COSV71128303; called by muse, mutect2, varscan2
- SPATA13 | c.1580C>T p.A527V | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57980258; called by muse, mutect2, varscan2
- MYOM2 | c.4329_4345del p.D1444Afs*22 | Frame Shift Del (DEL) | VAF 10/121 reads (8%) | called by mutect2, pindel
- CDON | c.3243C>T p.H1081= | Silent (SNP) | VAF 78/173 reads (45%) | catalogued as rs756812421, COSV54995691; called by muse, mutect2, varscan2
- ELF4 | c.861G>T p.V287= | Silent (SNP) | VAF 31/126 reads (25%) | catalogued as rs1392703852, COSV57454191; called by muse, mutect2, varscan2
- LATS2 | c.2679C>A p.L893= | Silent (SNP) | VAF 18/29 reads (62%) | catalogued as COSV66878384; called by muse, mutect2, varscan2
- NAV3 | c.2916C>G p.P972= | Silent (SNP) | VAF 105/262 reads (40%) | catalogued as rs754614139, COSV57101797; called by muse, mutect2, varscan2
- NLRP4 | c.741G>T p.L247= | Silent (SNP) | VAF 46/204 reads (23%) | catalogued as COSV56720007; called by muse, mutect2, varscan2
- OR6A2 | c.348G>A p.E116= | Silent (SNP) | VAF 67/135 reads (50%) | catalogued as COSV60264626, COSV60265540; called by muse, mutect2, varscan2
- RECQL5 | c.378G>T p.L126= | Silent (SNP) | VAF 91/402 reads (23%) | catalogued as COSV53129634; called by muse, mutect2, varscan2
- SIGLEC9 | c.429C>A p.T143= | Silent (SNP) | VAF 54/178 reads (30%) | catalogued as COSV51586418, COSV51586782; called by muse, mutect2, varscan2
- TAZ | c.678C>A p.P226= | Silent (SNP) | VAF 52/146 reads (36%) | catalogued as CD131100, COSV54797131; called by muse, mutect2, varscan2
- TTC39C | c.699G>C p.V233= (on ENST00000317571 / NM_001135993.2; = p.V172= on NM_153211.4) | Silent (SNP) | VAF 55/111 reads (50%) | catalogued as COSV100455113, COSV58219801; called by muse, mutect2, varscan2
- SNRPN | chr15:24980034 C>T | 3'Flank (SNP) | VAF 12/26 reads (46%) | catalogued as rs749867383; called by muse, mutect2, varscan2
